Surgical pathology report (de-identified scan), TCGA case TCGA-NK-A5CT, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Washington University - Rush University, specimen TCGA-NK-A5CT-01A (Primary Tumor).

[page 1 of 4]
ICD-0-3

Carcinoma, squamous cell
80743
Site; Lung, lower lobe
C343
JW 1/14/13

PATHOLOGY SURGICAL

Results

Status: Final result

Entry Date

Component Results

PATHOLOGY RESULT:

Department of Pathology

Final

Clinical Data Repository* This report may not match the original report format

FINAL DIAGNOSIS

- A. (Lymph node, level 9; biopsy): Fragments of lymphoid tissue, negative for malignancy.
- B. (Lymph node, level 7; biopsy): Fragments of lymphoid tissue, negative for malignancy.
- C. (Lymph node, level 7; biopsy): Fragments of lymphoid tissue, negative for malignancy.
- D. (Lymph node, level 11; biopsy): Fragments of lymphoid tissue, negative for malignancy.
- E. (Lung, left lower lobe; lobectomy): Moderately differentiated squamous cell carcinoma, measuring 2.8 x 2.7 x 2.1 cm, with associated necrosis. No convincing lymphovascular invasion noted. Visceral pleura, bronchial margin, and vascular margin are free of tumor. Eight benign peribronchial lymph nodes. Stage pT1N0Mx. See note.
- F. (Lymph node, level 5; biopsy): Fragments of lymphoid tissue, negative for malignancy.

INTRAOPERATIVE CONSULTATION

- E. FROZEN:LEFT LOWER LOBECTOMY FROZEN ON TUMOR: Poorly differentiated

[page 2 of 4]
carcinoma. (E91, TP, smear)

F. FROZEN: LEVEL 5 LYMPH NODE: Anthracotic lymph node without evidence of malignancy. (F91, TP, smear)

NOTE

E. Lung Cancer Summary

Specimen type: Lobectomy

Tumor location: Left lower lobe

Tumor size: 2.8 x 2.7 x 2.1 cm

Histologic type: Squamous cell carcinoma

Histologic grade: 2

Status of margins:

Bronchial: Negative

Vascular: Negative

Parenchymal: Negative

Pleural: Negative

Visceral/Parietal pleural invasion: Absent

Lymphatic vascular invasion: Absent

Lymph node status: Negative

Extension into other structures: Absent

Non-neoplastic pathology: N/A

TNM stage: pT1N0Mx

GROSS DESCRIPTION

A. The specimen is labeled "level 9 node." Received fresh is a < 1 g specimen, consisting of a fragment of yellow and black soft tissue (0.9 x 0.5 x 0.3 cm). The entire specimen is wrapped and submitted in cassette A1. DB

B. The specimen is labeled "level 7 lymph node." Received fresh is a < 1 g specimen, consisting of a single fragment of red-black soft tissue (0.6 x 0.3 x 0.3 cm). The entire specimen is wrapped and submitted in cassette B1. DB

C. The specimen is labeled "level 7 lymph node." Received fresh is a < 1 g specimen, consisting of multiple fragments of red and black soft tissue (1.4 x 0.4 x 0.3 cm). The entire specimen is wrapped and submitted in cassette C1.

D. The specimen is labeled "level 11L lymph node." Received fresh is a < 1 g specimen, consisting of two fragments of red-black soft tissue (1.2 x 1.1 x 0.7 cm in aggregate). The entire specimen is wrapped and submitted in cassette D1.

E. The specimen is labeled "left lower lobectomy." Received fresh for frozen section is a 192 g specimen, consisting of a lobectomy (22 x 15 x 4.5 cm). The surface of the specimen is inked red. The specimen is sectioned to show a well-circumscribed, tan-gray, nodular mass (2.8 x 2.7 x 2.1 cm) located 1.1 cm from the visceral pleura and > 1 cm from the bronchial margin. The remainder of the specimen shows a homogenous, red-brown, soft cut surface. No other

[page 3 of 4]
lesions or masses are present. Gross pictures are taken.

A representative section of the tumor is submitted for frozen section with the remnant placed in cassette E91. The remainder of the sections are submitted as follows: E1 bronchial margin; E2 vascular margin; E3 tumor with nearest visceral pleural margin; E4 through E7 representative sections of the tumor; E8 lung parenchyma away from the tumor; E9 three peribronchial lymph nodes; and E10 three peribronchial lymph nodes.

F. The specimen is labeled level 5 lymph node. Received fresh for frozen, is a fragment of yellow-black soft tissue (1.1 x 0.9 x 0.4 cm). One touch prep and one smear are obtained. The specimen is bisected and submitted in its entirety for frozen section with a remnant placed in cassette F91.

SPECIMEN(S) RECEIVED

A: LEVEL 9 NODE

B: LEVEL 7 LYMPH NODE

C: FRESH ROUTINE - LEVEL 7 LYMPH NODE

D: FRESH ROUTINE - LEVEL 11 L LYMPH NODE

E: FROZEN:LEFT LOWE LOBECTOMY FROZEN ON TUMOR

F: FROZEN:LEVEL 5 LYMPH NODE

* The above listed tests (if any) were developed and the performance characteristics determined by Department of Pathology. These tests have not been cleared or approved for commercial use by the U.S. Food and Drug Administration. The FDA has determined that FDA review is not required for such in-house assays. (21 CFR 809.30(e))

OPERATIVE INFORMATION

DIAGNOSIS: LUNG CANCER; PROCEDURE: BRONCHOSCOPY FLEXIBLE FIBEROPTIC, THORACOSCOPY VIDEO ASSISTED

INTRADEPARTMENT CONSULTATION PATHOLOGIST: QA COMMITTEE

ICD-9(s): 162.5

CPT(s): A: 88305

B: 88305

C: 88305

D: 88305

E: 88309, 88331, 88333, 88334

F: 88305, 88331, 88333, 88334

The attending pathologist was physically present when this specimen was diagnosed, and actively participated in all key decisions.

Lab and Collection

PATHOLOGY SURGICAL

Pathology

[page 4 of 4]
Procedure Location:

XUE	12/10/12	

Source: NCI Genomic Data Commons file bbbef296-ff8b-456a-9306-d2ba2c8ebb70 (TCGA-NK-A5CT.E336C87E-F021-4D95-BE95-ACA979B023CA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).